Somatic mutation profile of tumor specimen TCGA-62-A46P-01A (aliquot TCGA-62-A46P-01A-11D-A24D-08) from TCGA case TCGA-62-A46P, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 65.7 years (23,993 days).
Specimen TCGA-62-A46P-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9d077108-4bf7-41a4-a80d-3b05a57bec2d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-62-A46P-10A (Blood Derived Normal), aliquot TCGA-62-A46P-10A-01D-A24F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5d5b01de-1a15-4783-95c4-8774a291ce37

The open-access MAF lists 292 somatic variants for this specimen: 226 protein-altering or splice-affecting, 59 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 193, Silent 59, Nonsense Mutation 22, Frame Shift Del 4, Splice Site 3, Intron 2, 3'UTR 2, RNA 2, 5'UTR 1, Frame Shift Ins 1, In Frame Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SCN3B | c.482T>C p.M161T | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs587777557, CM108272, COSV100173700; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.216A>T p.Q72H | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as COSV101330020; called by muse, varscan2
- ABCA13 | c.6034G>T p.D2012Y | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.861); catalogued as COSV101330021; called by muse, mutect2, varscan2
- ABCA13 | c.14013G>T p.L4671F | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV101291304; called by muse, mutect2, varscan2
- ABCB1 | c.3065G>T p.S1022I | Missense Mutation (SNP) | VAF 35/64 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as COSV99712795; called by muse, mutect2, varscan2
- ABCD4 | c.1696G>T p.G566C | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100084219, COSV53990837; called by mutect2, varscan2
- ADAM20 | c.80G>T p.G27V | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.271); catalogued as COSV99833401; called by muse, mutect2, varscan2
- ADAMTS14 | c.3129G>T p.Q1043H | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as COSV100941522; called by muse, mutect2, varscan2
- ADGRA2 | c.2539C>A p.L847I | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55105227; called by muse, mutect2, varscan2
- AGAP1 | c.508G>C p.E170Q | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); catalogued as COSV100364772; called by muse, mutect2, varscan2
- AGPAT1 | c.434T>G p.I145S | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV100421610; called by muse, mutect2, varscan2
- AHNAK2 | c.2641C>G p.L881V | Missense Mutation (SNP) | VAF 14/332 reads (4%) | SIFT tolerated (0.33); PolyPhen benign (0.024); catalogued as COSV100317064, COSV60910570, COSV60915598; called by muse, mutect2
- AKAP8L | c.768G>A p.M256I | Missense Mutation (SNP) | VAF 51/205 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0.047); catalogued as rs1242068930, COSV101275788; called by muse, mutect2, varscan2
- AOX1 | c.3701A>G p.D1234G | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99613580; called by muse, mutect2, varscan2
- AP2A2 | c.564G>T p.W188C | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100172804; called by muse, mutect2, varscan2
- APOBEC3A | c.172C>A p.Q58K | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV99970329, COSV99970332; called by muse, mutect2, varscan2
- ARID2 | c.5393C>A p.S1798* | Nonsense Mutation (SNP) | VAF 7/33 reads (21%) | catalogued as COSV100535968, COSV57616604; called by muse, mutect2, varscan2
- ARID5B | c.1559C>A p.T520K | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV99689499; called by muse, mutect2, varscan2
- ARMC5 | c.1634G>T p.G545V | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.463); catalogued as COSV99192456; called by muse, mutect2, varscan2
- ASB2 | c.557G>A p.R186H | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.465); catalogued as rs375067990; called by muse, mutect2
- ASPHD1 | c.806C>T p.P269L | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs764035673, COSV100435338; called by muse, mutect2, varscan2
- ATG2B | c.1291A>G p.M431V | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1397816846, COSV100737937; called by muse, mutect2, varscan2
- BCL2L13 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs972912134, COSV58225044; called by muse, mutect2, varscan2
- BEST1 | c.1284C>A p.N428K | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV99861282; called by muse, mutect2, varscan2
- BOC | c.1201C>A p.H401N | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.21); catalogued as COSV99848564; called by muse, mutect2
- BRINP3 | c.1240G>T p.G414C | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.848); catalogued as COSV100818655, COSV100819599; called by muse, mutect2, varscan2
- CACNA2D4 | c.618C>A p.S206R | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.475); catalogued as COSV99765499; called by muse, mutect2, varscan2
- CAPS2 | c.1008-1G>C p.X336_splice | Splice Site (SNP) | VAF 7/45 reads (16%) | catalogued as COSV100157628; called by muse, mutect2, varscan2
- CD5 | c.184C>A p.Q62K | Missense Mutation (SNP) | VAF 58/149 reads (39%) | SIFT tolerated (0.38); PolyPhen benign (0.027); catalogued as COSV100759800; called by muse, mutect2, varscan2
- CDH10 | c.2309C>G p.P770R | Missense Mutation (SNP) | VAF 45/149 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52575708, COSV52585316; called by muse, mutect2, varscan2
- CDH23 | c.94A>T p.T32S | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as COSV99820431; called by muse, mutect2, varscan2
- CDH23 | c.4265C>A p.S1422Y | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as COSV99820434; called by muse, mutect2, varscan2
- CDH4 | c.1996C>A p.R666S | Missense Mutation (SNP) | VAF 71/108 reads (66%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100848698, COSV64671570; called by muse, mutect2, varscan2
- CHST5 | c.1157C>G p.A386G | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV100291890; called by muse, mutect2, varscan2
- CILP2 | c.883G>T p.V295L | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.052); catalogued as COSV99364597; called by muse, mutect2, varscan2
- CKAP2 | c.975G>T p.R325S (on ENST00000378037 / NM_001098525.2; = p.R324S on NM_018204.5) | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.306); catalogued as COSV99318234; called by muse, mutect2, varscan2
- CNTNAP2 | c.3147G>T p.E1049D | Missense Mutation (SNP) | VAF 33/139 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.621); catalogued as COSV100665504; called by muse, mutect2, varscan2
- COL1A1 | c.1003-2A>T p.X335_splice | Splice Site (SNP) | VAF 5/11 reads (45%) | catalogued as CS071165, COSV99867017; called by muse, mutect2, varscan2
- CPLANE2 | c.113-2A>T p.X38_splice | Splice Site (SNP) | VAF 17/47 reads (36%) | catalogued as COSV100983265; called by muse, mutect2, varscan2
- CTDP1 | c.413A>G p.N138S | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.855); catalogued as rs754182939, COSV99310434; called by muse, mutect2, varscan2
- CUX2 | c.2540C>A p.P847H | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV99919422; called by muse, mutect2
- DCTN6 | c.154G>C p.E52Q | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.275); catalogued as COSV99074009, COSV99644966; called by muse, mutect2
- DEFB126 | c.171C>A p.D57E | Missense Mutation (SNP) | VAF 73/112 reads (65%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV101215640; called by muse, mutect2, varscan2
- DENND1A | c.888G>T p.R296S | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as COSV101010521; called by muse, mutect2, varscan2
- DENND1A | c.887G>T p.R296M | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.375); catalogued as COSV101010523; called by muse, mutect2, varscan2
- DENND5B | c.820G>T p.A274S | Missense Mutation (SNP) | VAF 6/8 reads (75%) | SIFT tolerated (0.05); PolyPhen benign (0.102); catalogued as COSV100171301; called by muse, mutect2, varscan2
- DEPDC5 | c.3331G>A p.V1111I (on ENST00000400246; = p.V1180I on NM_014662.5) | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.883); catalogued as COSV99835103; called by muse, mutect2, varscan2
- DLGAP2 | c.1489C>A p.L497M | Missense Mutation (SNP) | VAF 9/10 reads (90%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV70105027; called by muse, mutect2, varscan2
- DLGAP2 | c.2350G>A p.E784K | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as rs938343477, COSV101421697; called by muse, mutect2, varscan2
- DNAH5 | c.1513G>T p.E505* | Nonsense Mutation (SNP) | VAF 23/56 reads (41%) | catalogued as rs906490504, COSV54242131, COSV99448644, COSV99455380; called by muse, mutect2
- DYTN | c.1152G>T p.Q384H | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV101510824; called by muse, mutect2, varscan2
- EIF3M | c.943G>T p.A315S | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as COSV100024971; called by muse, varscan2
- ELP4 | c.1090G>T p.E364* (on ENST00000350638; = p.E363* on NM_019040.5) | Nonsense Mutation (SNP) | VAF 4/31 reads (13%) | catalogued as COSV100635347; called by muse, mutect2, varscan2
- EMG1 | c.646A>G p.M216V | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV99781058; called by muse, mutect2, varscan2
- EOMES | c.1268C>A p.T423N | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.192); catalogued as COSV99841883; called by muse, mutect2, varscan2
- EPHA3 | c.1150C>A p.P384T | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60699578, COSV60715314; called by muse, mutect2, varscan2
- ERICH3 | c.2524G>T p.A842S | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.012); catalogued as COSV100444080; called by muse, mutect2, varscan2
- FAM135B | c.442C>A p.L148M | Missense Mutation (SNP) | VAF 94/187 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99356908; called by muse, mutect2, varscan2
- FANCA | c.1580A>T p.N527I | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.343); catalogued as rs767196065, COSV101224704; called by muse, mutect2, varscan2
- FBLN1 | c.1468G>T p.G490W | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs145539977, COSV99410461; called by muse, mutect2, varscan2
- FBXL14 | c.316A>T p.N106Y | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.291); catalogued as COSV100201475; called by muse, mutect2
- FCAR | c.349C>A p.L117M | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100629056; called by muse, mutect2, varscan2
- FEZ2 | c.892A>G p.M298V | Missense Mutation (SNP) | VAF 43/143 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.013); catalogued as COSV100002047; called by muse, mutect2, varscan2
- FGF10 | c.77T>G p.L26W | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as COSV99240448; called by muse, mutect2, varscan2
- FMNL3 | c.1712T>A p.L571Q | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV99526008; called by muse, mutect2, varscan2
- FNDC1 | c.1792G>T p.D598Y | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.707); catalogued as COSV51951553; called by muse, mutect2, varscan2
- FREM2 | c.2681A>G p.D894G | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99748392; called by muse, mutect2, varscan2
- FRZB | c.886C>A p.L296I | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV99717348; called by muse, mutect2, varscan2
- FYCO1 | c.2749G>T p.V917L | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs373989195, COSV99945553; called by muse, mutect2, varscan2
- GAB4 | c.1168C>A p.L390I | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as COSV101271958, COSV68755234; called by muse, mutect2, varscan2
- GABRA5 | c.1053G>T p.W351C | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV100165052; called by muse, mutect2, varscan2
- GLI3 | c.935C>T p.T312M | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs772929930, COSV67894711; ClinVar: benign; called by muse, mutect2, varscan2
- GLP1R | c.725A>C p.Y242S | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (0.74); PolyPhen benign (0.206); catalogued as COSV100952558; called by muse, mutect2, varscan2
- GOLGA3 | c.2835G>T p.Q945H | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.188); catalogued as rs773571644, COSV99202944; called by muse, mutect2, varscan2
- GPR158 | c.2669A>T p.K890I | Missense Mutation (SNP) | VAF 47/113 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100893346; called by muse, mutect2, varscan2
- GPR45 | c.577C>A p.R193S | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.756); catalogued as COSV51524021, COSV99306902; called by muse, mutect2, varscan2
- GREB1 | c.5712G>C p.Q1904H | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV99302780; called by muse, mutect2, varscan2
- GRM7 | c.1865G>T p.R622L | Missense Mutation (SNP) | VAF 42/130 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as CM124540, COSV100736180; called by muse, mutect2, varscan2
- GSPT2 | c.1132G>C p.G378R | Missense Mutation (SNP) | VAF 26/38 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100468108; called by muse, mutect2, varscan2
- GUCY1A2 | c.1371G>T p.E457D | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99974184; called by muse, mutect2, varscan2
- GZMM | c.773G>T p.*258Lext*25 | Nonstop Mutation (SNP) | VAF 10/34 reads (29%) | catalogued as COSV99198831; called by muse, mutect2, varscan2
- HARS2 | c.976G>T p.A326S | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV99218047; called by muse, mutect2, varscan2
- HERC1 | c.131A>G p.N44S | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as rs570728689, COSV101496510; called by muse, mutect2, varscan2
- HMCES | c.8G>C p.G3A | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100135537; called by muse, mutect2, varscan2
- HOXB2 | c.71C>A p.S24Y | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV100344603; called by muse, mutect2, varscan2
- HRH2 | c.395C>A p.P132Q | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as COSV99199605; called by muse, mutect2, varscan2
- HRNR | c.833G>T p.G278V | Missense Mutation (SNP) | VAF 94/312 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.767); catalogued as rs772449207, COSV100913370; called by muse, mutect2, varscan2
- HSP90AB1 | c.2134G>T p.E712* | Nonsense Mutation (SNP) | VAF 24/60 reads (40%) | catalogued as rs372383252, COSV99241051; called by muse, mutect2, varscan2
- IDH3A | c.224G>C p.G75A | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.33); PolyPhen benign (0.021); catalogued as COSV100210824; called by muse, mutect2, varscan2
- IGHD | c.661G>T p.E221* | Nonsense Mutation (SNP) | VAF 3/11 reads (27%) | catalogued as COSV101162851; called by muse, mutect2
- IL26 | c.118C>A p.Q40K | Missense Mutation (SNP) | VAF 27/139 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV99970868; called by muse, mutect2, varscan2
- IRX1 | c.631G>T p.E211* | Nonsense Mutation (SNP) | VAF 15/52 reads (29%) | catalogued as COSV57362412; called by muse, mutect2, varscan2
- ITGAE | c.116G>T p.S39I | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV99560842; called by muse, mutect2, varscan2
- ITIH4 | c.1661A>T p.Q554L | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV99819251; called by muse, mutect2, varscan2
- KCNA5 | c.1275G>T p.K425N | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as COSV99363832; called by muse, mutect2, varscan2
- KCNA6 | c.355G>T p.E119* | Nonsense Mutation (SNP) | VAF 23/68 reads (34%) | catalogued as COSV99768553; called by muse, mutect2, varscan2
- KCNH6 | c.2411C>A p.P804Q | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.007); catalogued as COSV100120966; called by mutect2, varscan2
- KCNK2 | c.127G>T p.V43L (on ENST00000444842 / NM_001017425.3; = p.V28L on NM_014217.4) | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.005); catalogued as COSV101222075; called by muse, mutect2, varscan2
- KCTD16 | c.698T>A p.L233Q | Missense Mutation (SNP) | VAF 37/70 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101568791; called by muse, mutect2, varscan2
- KMT2A | c.6020G>A p.R2007K | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.1); catalogued as rs782409744, COSV100628576; called by muse, mutect2
- KRT35 | c.1283C>T p.P428L | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV99877756; called by muse, mutect2, varscan2
- KRT39 | c.560C>A p.A187D | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as COSV100842193; called by muse, mutect2, varscan2
- KRT74 | c.410G>A p.R137H | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.117); catalogued as rs747946851, COSV59770370; called by muse, mutect2, varscan2
- LAIR2 | c.302G>A p.C101Y | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56620730; called by muse, mutect2, varscan2
- LDB2 | c.1009G>T p.E337* | Nonsense Mutation (SNP) | VAF 57/159 reads (36%) | catalogued as COSV100453424, COSV58766987; called by muse, varscan2
- LMOD3 | c.1445C>A p.P482H | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as rs969581155, COSV101341988; called by muse, mutect2, varscan2
- LPA | c.3956C>G p.T1319S | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.092); catalogued as COSV100306672; called by muse, mutect2, varscan2
- LPIN3 | c.2036A>T p.Q679L | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as COSV100182507; called by muse, mutect2, varscan2
- LRP1 | c.10295G>T p.R3432L | Missense Mutation (SNP) | VAF 52/129 reads (40%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); catalogued as COSV99675534; called by muse, mutect2, varscan2
- LRP1B | c.1117G>T p.A373S | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV101255666; called by muse, mutect2, varscan2
- LRRIQ1 | c.4540A>T p.R1514* | Nonsense Mutation (SNP) | VAF 26/75 reads (35%) | catalogued as COSV101280059; called by muse, mutect2, varscan2
- LRRIQ3 | c.1544G>T p.R515L | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.75); catalogued as COSV100598687, COSV63044305; called by muse, mutect2, varscan2
- LRRTM1 | c.1375C>A p.Q459K | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.021); catalogued as COSV54440271, COSV54444061; called by muse, mutect2, varscan2
- MAP1B | c.875C>T p.S292F | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99702205; called by muse, mutect2, varscan2
- MCF2L | c.3311G>C p.G1104A (on ENST00000375608; = p.G1072A on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.116); catalogued as COSV99995682; called by muse, mutect2, varscan2
- MCF2L2 | c.1110C>A p.S370R | Missense Mutation (SNP) | VAF 51/120 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV100192193; called by muse, mutect2, varscan2
- MED20 | c.124G>T p.D42Y | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99539816; called by muse, mutect2, varscan2
- MFHAS1 | c.1937C>T p.A646V | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as COSV99359503; called by muse, mutect2
- MIIP | c.810G>T p.Q270H | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.66); catalogued as COSV99337558; called by muse, mutect2, varscan2
- MOGS | c.1937C>T p.A646V | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.538); catalogued as rs536613092, COSV99270471; called by muse, mutect2, varscan2
- MOGS | c.457G>A p.G153S | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99280950; called by muse, mutect2, varscan2
- MUC16 | c.14938C>A p.P4980T | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.047); catalogued as COSV101199515, COSV67498760; called by muse, mutect2, varscan2
- MUC16 | c.8224G>T p.G2742C | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV101199516; called by muse, mutect2, varscan2
- MYH13 | c.301G>A p.A101T | Missense Mutation (SNP) | VAF 62/153 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.153); catalogued as COSV99353571, COSV99354319; called by muse, mutect2, varscan2
- MYH6 | c.3273G>T p.Q1091H | Missense Mutation (SNP) | VAF 15/174 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.018); catalogued as COSV100676472; called by muse, mutect2
- MYH8 | c.2710G>T p.A904S | Missense Mutation (SNP) | VAF 58/192 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.039); catalogued as COSV101238379; called by muse, mutect2, varscan2
- NALCN | c.1726G>A p.A576T | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99214489; called by muse, mutect2, varscan2
- NAV3 | c.5282C>A p.S1761* | Nonsense Mutation (SNP) | VAF 45/93 reads (48%) | catalogued as COSV99889735; called by muse, mutect2, varscan2
- NEFM | c.2003C>A p.P668H | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as COSV99647193; called by muse, varscan2
- NOP53 | c.439C>T p.R147W | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1451127380, COSV99884294; called by muse, mutect2
- NPHS1 | c.2857A>C p.T953P | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as COSV100799772; called by muse, mutect2, varscan2
- NRF1 | c.1129G>T p.E377* | Nonsense Mutation (SNP) | VAF 6/44 reads (14%) | catalogued as COSV99781712; called by muse, mutect2, varscan2
- NRG1 | c.1624G>A p.A542T (on ENST00000405005 / NM_013964.5; = p.A547T on NM_013956.5) | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs776391266, COSV55154820; called by mutect2, varscan2
- NUTM2F | c.122C>T p.P41L | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as rs573696663, COSV53561134, COSV99480041; called by muse, mutect2, varscan2
- NYAP2 | c.589C>T p.R197* | Nonsense Mutation (SNP) | VAF 6/127 reads (5%) | catalogued as COSV56013284, COSV56015077; called by muse, mutect2
- OGDHL | c.1871G>A p.R624H | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs746449761, COSV65103575; called by muse, mutect2, varscan2
- OR10Q1 | c.268T>G p.L90V | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV100372255, COSV57470934; called by muse, mutect2
- OR10X1 | c.828G>T p.L276F | Missense Mutation (SNP) | VAF 24/204 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.892); catalogued as COSV100936632; called by muse, mutect2, varscan2
- OR12D3 | c.108C>G p.N36K | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as COSV101011231, COSV101011459; called by muse, mutect2, varscan2
- OR4A16 | c.416G>C p.C139S | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.461); catalogued as COSV100125170, COSV59042537; called by muse, mutect2, varscan2
- OR4N5 | c.407T>A p.M136K | Missense Mutation (SNP) | VAF 46/181 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV100374088; called by muse, mutect2, varscan2
- OR5T3 | c.400C>A p.H134N | Missense Mutation (SNP) | VAF 53/157 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as rs757084705, COSV100282764, COSV57379949; called by muse, mutect2, varscan2
- OR5W2 | c.574A>T p.T192S | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV100747598; called by muse, mutect2, varscan2
- OTOF | c.4758C>A p.S1586R (on ENST00000272371 / NM_194248.3; = p.S819R on NM_004802.4) | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99717371; called by muse, mutect2, varscan2
- OTX2 | c.590G>T p.G197V (on ENST00000408990 / NM_172337.3; = p.G205V on NM_021728.4) | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV100257892, COSV59767378; called by muse, mutect2, varscan2
- PAX8 | c.166G>T p.G56C | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99639394; called by muse, mutect2, varscan2
- PCDHA4 | c.800C>A p.S267* | Nonsense Mutation (SNP) | VAF 16/54 reads (30%) | catalogued as COSV100793349, COSV100793444; called by muse, mutect2
- PCDHGA2 | c.1594G>T p.V532L | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.651); catalogued as COSV99536273; called by muse, mutect2, varscan2
- PDE4B | c.1625G>A p.G542D | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100303224; called by muse, mutect2
- PIF1 | c.736C>G p.P246A | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs1035875777, COSV51423913, COSV99164903; called by muse, varscan2
- PIWIL2 | c.1564A>T p.N522Y | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0.251); catalogued as COSV100769357; called by muse, mutect2
- PLAU | c.863G>A p.C288Y | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101032316; called by muse, mutect2, varscan2
- PLIN4 | c.3761G>A p.G1254E (on ENST00000301286; = p.G1269E on NM_001367868.2) | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.45); PolyPhen benign (0.236); catalogued as rs1331479868, COSV100012198; called by muse, mutect2, varscan2
- PLXNA2 | c.4138A>G p.M1380V | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100885374; called by muse, mutect2, varscan2
- PLXNB1 | c.6248G>T p.G2083V | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV99602725; called by muse, mutect2, varscan2
- PNISR | c.2059G>T p.E687* | Nonsense Mutation (SNP) | VAF 11/20 reads (55%) | catalogued as COSV100984342; called by muse, mutect2, varscan2
- PPP1R12A | c.1885G>T p.A629S | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT tolerated (0.4); PolyPhen benign (0.138); catalogued as COSV99700232; called by muse, mutect2, varscan2
- PPP1R13L | c.1535G>T p.R512L | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs537319636, COSV100714733; called by muse, mutect2, varscan2
- PRAMEF5 | c.1411G>T p.A471S | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV100871241; called by muse, mutect2, varscan2
- PRDM14 | c.127C>A p.L43M | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as COSV99400075; called by muse, mutect2, varscan2
- PRPF3 | c.1478C>T p.P493L | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100254732; called by muse, mutect2, varscan2
- PSG3 | c.84G>T p.W28C | Missense Mutation (SNP) | VAF 60/142 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100548901; called by muse, mutect2, varscan2
- PTGER3 | c.526G>T p.A176S | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT tolerated (0.54); PolyPhen benign (0.058); catalogued as COSV60695497; called by muse, mutect2
- PXDNL | c.756C>A p.Y252* | Nonsense Mutation (SNP) | VAF 42/75 reads (56%) | catalogued as COSV100683169; called by muse, mutect2, varscan2
- RABGGTB | c.137G>T p.R46I | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100175032; called by muse, mutect2, varscan2
- RELN | c.4347G>T p.E1449D | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT tolerated (0.17); PolyPhen benign (0.024); catalogued as COSV100633417, COSV58984774; called by muse, mutect2, varscan2
- RFWD3 | c.2187G>T p.W729C | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as COSV100736217; called by muse, mutect2, varscan2
- RHD | c.217A>T p.S73C | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.02); catalogued as COSV100155029; called by muse, mutect2, varscan2
- RIMS1 | c.2864C>A p.S955Y | Missense Mutation (SNP) | VAF 9/11 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99325974; called by muse, mutect2, varscan2
- RYR2 | c.9613T>G p.C3205G | Missense Mutation (SNP) | VAF 102/174 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.664); catalogued as COSV100769624; called by muse, mutect2, varscan2
- SCFD1 | c.667G>C p.V223L | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as COSV100356306; called by muse, mutect2, varscan2
- SEC61A1 | c.1288G>A p.A430T | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.309); catalogued as COSV99684834; called by muse, mutect2, varscan2
- SERPINB4 | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as rs1272828136, COSV100345644; called by muse, mutect2, varscan2
- SETD2 | c.7572T>A p.C2524* | Nonsense Mutation (SNP) | VAF 14/48 reads (29%) | catalogued as COSV100338770; called by muse, mutect2, varscan2
- SH3GL2 | c.973G>T p.E325* | Nonsense Mutation (SNP) | VAF 5/23 reads (22%) | catalogued as COSV101014250; called by muse, mutect2, varscan2
- SIGLEC6 | c.121G>T p.V41L | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as rs753368300, COSV100585320, COSV58433404; called by muse, mutect2, varscan2
- SLC10A2 | c.972G>T p.E324D | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV55358350, COSV99807879; called by mutect2, varscan2
- SLC13A4 | c.1080G>C p.K360N | Missense Mutation (SNP) | VAF 6/144 reads (4%) | SIFT tolerated (0.47); PolyPhen benign (0.312); catalogued as COSV100818861; called by muse, mutect2
- SLC22A2 | c.145C>A p.H49N | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as COSV100870975; called by muse, mutect2, varscan2
- SLC2A3 | c.314G>T p.G105V | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.58); catalogued as COSV99306500; called by muse, mutect2, varscan2
- SLC35A5 | c.1158G>T p.R386S | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV99656721, COSV99656763; called by muse, mutect2, varscan2
- SLC36A3 | c.1176C>A p.D392E | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.232); catalogued as COSV100077551; called by muse, mutect2, varscan2
- SLC8A2 | c.454G>C p.G152R | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52639393, COSV99369865, COSV99370429; called by muse, mutect2, varscan2
- SLITRK2 | c.2305G>T p.A769S | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as COSV59425870; called by muse, mutect2, varscan2
- SLTM | c.1880G>T p.R627L | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.187); catalogued as COSV99989106; called by muse, mutect2, varscan2
- STK11 | c.208G>T p.E70* | Nonsense Mutation (SNP) | VAF 14/25 reads (56%) | catalogued as CM981865, COSV58820140; called by muse, mutect2, varscan2
- SUPT6H | c.1868A>T p.K623I | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.397); catalogued as COSV100112312; called by muse, mutect2, varscan2
- SYCP2 | c.907G>T p.E303* | Nonsense Mutation (SNP) | VAF 8/32 reads (25%) | catalogued as COSV100697882, COSV100698191; called by muse, mutect2, varscan2
- SYT14 | c.727C>G p.Q243E | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99655032; called by muse, mutect2, varscan2
- SYT16 | c.770A>T p.E257V | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.036); catalogued as COSV101413568; called by muse, mutect2, varscan2
- SYT4 | c.367C>A p.P123T | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.033); catalogued as COSV99673673; called by muse, mutect2, varscan2
- TAAR6 | c.412C>A p.L138M | Missense Mutation (SNP) | VAF 31/265 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99256630, COSV99256971; called by muse, mutect2, varscan2
- TESMIN | c.13C>G p.P5A | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.986); catalogued as COSV99663485, COSV99663605; called by muse, mutect2, varscan2
- TET1 | c.6040G>T p.A2014S | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV101018034; called by muse, mutect2, varscan2
- TIAM1 | c.2989A>T p.K997* | Nonsense Mutation (SNP) | VAF 14/34 reads (41%) | catalogued as COSV99734511; called by muse, mutect2, varscan2
- TLL2 | c.1350C>A p.N450K | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.559); catalogued as COSV100780239; called by muse, mutect2, varscan2
- TLN1 | c.3122C>T p.A1041V | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.967); catalogued as COSV100147612; called by muse, mutect2, varscan2
- TPTE | c.533T>A p.F178Y (on ENST00000618007 / NM_199261.4; = p.F160Y on NM_199259.4) | Missense Mutation (SNP) | VAF 26/187 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.705); catalogued as rs1255908843; called by muse, mutect2, varscan2
- TRUB2 | c.964A>G p.T322A | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs764898765, COSV100867844; called by muse, mutect2, varscan2
- UGT2B15 | c.224A>C p.E75A | Missense Mutation (SNP) | VAF 51/140 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV100592297; called by muse, mutect2, varscan2
- UMOD | c.95G>T p.C32F | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM064352, COSV100208232; called by muse, mutect2, varscan2
- UNC5D | c.2030C>A p.A677E | Missense Mutation (SNP) | VAF 55/112 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776038058, COSV54795923, COSV99774489; called by muse, mutect2, varscan2
- USP13 | c.2159G>T p.G720V | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.904); catalogued as rs748591863, COSV99831047; called by muse, mutect2, varscan2
- VWC2L | c.623C>A p.P208H | Missense Mutation (SNP) | VAF 41/119 reads (34%) | SIFT tolerated (0.6); PolyPhen benign (0.061); catalogued as COSV100435165; called by muse, mutect2, varscan2
- WDFY3 | c.3105A>T p.R1035S | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.045); catalogued as COSV99883105; called by muse, mutect2, varscan2
- WDR47 | c.2380A>T p.T794S (on ENST00000369962 / NM_001142551.2; = p.T795S on NM_014969.5) | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT tolerated (0.6); PolyPhen benign (0.133); catalogued as COSV100728319; called by muse, mutect2, varscan2
- XIRP2 | c.2123C>A p.P708Q (on ENST00000628543; = p.P883Q on NM_152381.6) | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99741849; called by muse, mutect2, varscan2
- ZBTB41 | c.1594A>C p.N532H | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV100963047; called by muse, mutect2, varscan2
- ZBTB49 | c.1241A>T p.K414I | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.163); catalogued as COSV100552441; called by muse, mutect2, varscan2
- ZFHX4 | c.199G>T p.E67* | Nonsense Mutation (SNP) | VAF 31/138 reads (22%) | catalogued as COSV51496059, COSV99261641; called by muse, mutect2, varscan2
- ZNF285 | c.874G>T p.E292* | Nonsense Mutation (SNP) | VAF 42/120 reads (35%) | catalogued as COSV100449965; called by muse, mutect2, varscan2
- ZNF521 | c.3379A>T p.I1127F | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.7); PolyPhen benign (0.017); catalogued as COSV100831933; called by muse, mutect2, varscan2
- ZNF578 | c.409G>T p.G137C | Missense Mutation (SNP) | VAF 44/148 reads (30%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as COSV101405040; called by muse, mutect2, varscan2
- ZNHIT1 | c.22G>T p.V8F | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.71); PolyPhen benign (0.114); catalogued as COSV99777964; called by muse, mutect2, varscan2
- ZNRF1 | c.465C>G p.D155E | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.082); catalogued as rs750168982, COSV57727967; called by muse, mutect2, varscan2
- ZZEF1 | c.8224G>C p.E2742Q | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV101067731; called by muse, mutect2, varscan2
- CFAP74 | c.805A>C p.K269Q | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- CHST12 | c.62_86del p.L21Qfs*50 | Frame Shift Del (DEL) | VAF 10/80 reads (13%) | called by mutect2, pindel
- CKAP5 | c.4908_4910del p.G1637del (on ENST00000529230 / NM_001008938.4; = p.G1577del on NM_014756.3) | In Frame Del (DEL) | VAF 7/63 reads (11%) | called by mutect2, pindel, varscan2
- ELF3 | c.1054dup p.Y352Lfs*119 | Frame Shift Ins (INS) | VAF 10/72 reads (14%) | called by mutect2, varscan2
- ERICH3 | c.2339del p.A780Gfs*9 | Frame Shift Del (DEL) | VAF 28/78 reads (36%) | called by mutect2, pindel, varscan2
- KIR3DL1 | c.891C>G p.F297L | Missense Mutation (SNP) | VAF 54/174 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- NELL2 | c.886del p.C296Afs*2 | Frame Shift Del (DEL) | VAF 8/37 reads (22%) | called by mutect2, pindel, varscan2
- NUP155 | c.307_309dup p.N103dup (on ENST00000231498 / NM_153485.3; = p.N44dup on NM_004298.4) | In Frame Ins (INS) | VAF 22/69 reads (32%) | called by mutect2, pindel, varscan2
- OR3A1 | c.461del p.C154Lfs*7 | Frame Shift Del (DEL) | VAF 26/112 reads (23%) | called by mutect2, pindel, varscan2
- TRAV1-2 | c.141C>A p.N47K | Missense Mutation (SNP) | VAF 49/139 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.195); called by muse, mutect2, varscan2
- ABCC11 | c.2487C>T p.Y829= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV100750703; called by muse, mutect2, varscan2
- ADCY10 | c.3699G>T p.L1233= | Silent (SNP) | VAF 11/108 reads (10%) | catalogued as COSV100896787; called by muse, mutect2, varscan2
- AHNAK2 | c.9471C>G p.A3157= | Silent (SNP) | VAF 110/345 reads (32%) | catalogued as COSV100317062; called by muse, mutect2, varscan2
- ANK1 | c.807C>A p.T269= | Silent (SNP) | VAF 42/81 reads (52%) | catalogued as COSV99224884; called by muse, mutect2, varscan2
- ANO3 | c.222C>A p.S74= | Silent (SNP) | VAF 31/105 reads (30%) | catalogued as COSV99882239; called by muse, mutect2, varscan2
- ARFGEF3 | c.3594G>T p.R1198= | Silent (SNP) | VAF 29/99 reads (29%) | catalogued as COSV99293192; called by muse, mutect2, varscan2
- ATP1A2 | c.1188T>C p.H396= | Silent (SNP) | VAF 18/66 reads (27%) | catalogued as COSV100767777; called by muse, mutect2, varscan2
- BAIAP2 | c.168G>T p.L56= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV100347947; called by muse, mutect2, varscan2
- CDC42EP4 | c.24G>T p.V8= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as COSV100231808; called by muse, mutect2, varscan2
- CHST8 | c.1149C>T p.T383= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as COSV99381003; called by muse, mutect2, varscan2
- CMYA5 | c.6354G>A p.E2118= | Silent (SNP) | VAF 25/63 reads (40%) | catalogued as COSV101484003; called by muse, mutect2, varscan2
- CPS1 | c.432G>T p.L144= | Silent (SNP) | VAF 8/103 reads (8%) | catalogued as COSV99242768; called by muse, mutect2
- CRACD | c.222C>T p.F74= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as COSV99949084; called by muse, mutect2, varscan2
- DDR2 | c.2373G>A p.Q791= | Silent (SNP) | VAF 37/140 reads (26%) | catalogued as COSV100906454; called by muse, mutect2, varscan2
- DNAH5 | c.1512G>T p.L504= | Silent (SNP) | VAF 24/58 reads (41%) | catalogued as COSV99448646; called by muse, mutect2
- DOCK2 | c.1854G>T p.L618= | Silent (SNP) | VAF 31/92 reads (34%) | catalogued as rs748195879, COSV56991642, COSV99911697; called by muse, mutect2, varscan2
- DSCAML1 | c.3009C>A p.T1003= (on ENST00000321322; = p.T943= on NM_020693.4) | Silent (SNP) | VAF 16/66 reads (24%) | catalogued as COSV100355643; called by muse, mutect2, varscan2
- FAM83D | c.504C>T p.D168= | Silent (SNP) | VAF 3/45 reads (7%) | catalogued as rs899383300, COSV99465168; called by muse, mutect2
- FCRL3 | c.1005C>A p.T335= | Silent (SNP) | VAF 40/72 reads (56%) | catalogued as rs757021147, COSV63845211; called by muse, mutect2, varscan2
- GLT8D2 | c.573G>A p.Q191= | Silent (SNP) | VAF 15/78 reads (19%) | catalogued as COSV100674033, COSV62562835; called by muse, mutect2, varscan2
- GP2 | c.999C>A p.A333= (on ENST00000381362 / NM_001007240.3; = p.A330= on NM_001502.4) | Silent (SNP) | VAF 23/87 reads (26%) | catalogued as COSV100221433; called by muse, mutect2, varscan2
- HUNK | c.732C>T p.I244= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as rs774875015, COSV54228777; called by muse, mutect2, varscan2
- KIAA1191 | c.729C>G p.A243= | Silent (SNP) | VAF 23/93 reads (25%) | catalogued as COSV100055392; called by muse, mutect2, varscan2
- KRT33B | c.1104C>A p.P368= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as COSV99290582; called by muse, mutect2, varscan2
- LATS2 | c.2856C>T p.C952= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as COSV101231538; called by muse, mutect2, varscan2
- MC5R | c.573C>A p.I191= | Silent (SNP) | VAF 176/579 reads (30%) | catalogued as COSV100229015, COSV61255526; called by muse, mutect2, varscan2
- MMRN1 | c.57G>T p.G19= | Silent (SNP) | VAF 14/69 reads (20%) | catalogued as COSV99306984; called by muse, mutect2, varscan2
- MSH4 | c.1914A>T p.P638= | Silent (SNP) | VAF 20/44 reads (45%) | catalogued as COSV99591397; called by muse, mutect2, varscan2
- MUC16 | c.7173C>A p.I2391= | Silent (SNP) | VAF 18/55 reads (33%) | catalogued as COSV101199517; called by muse, mutect2, varscan2
- MYOM2 | c.2187C>A p.L729= | Silent (SNP) | VAF 36/169 reads (21%) | catalogued as COSV100037340; called by muse, mutect2, varscan2
- OBSCN | c.6939G>T p.V2313= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as COSV99476686; called by muse, mutect2, varscan2
- OR10H1 | c.684G>A p.K228= | Silent (SNP) | VAF 4/60 reads (7%) | catalogued as rs1404232555, COSV58472827; called by muse, mutect2
- OR8J3 | c.225T>A p.T75= | Silent (SNP) | VAF 15/101 reads (15%) | catalogued as COSV100040765; called by muse, mutect2, varscan2
- PCDHA4 | c.798C>A p.A266= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as COSV100793348; called by muse, mutect2
- PCDHB10 | c.2031C>A p.A677= | Silent (SNP) | VAF 48/122 reads (39%) | catalogued as rs781867544, COSV99504135; called by muse, mutect2, varscan2
- PCNX2 | c.1746G>C p.L582= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV99267086; called by muse, mutect2, varscan2
- PGK1 | c.480C>T p.V160= | Silent (SNP) | VAF 15/25 reads (60%) | catalogued as COSV100965315; called by muse, mutect2, varscan2
- PIK3R5 | c.225C>T p.Y75= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs760125091, COSV99353210; called by muse, mutect2
- PISD | c.975C>T p.N325= (on ENST00000439502 / NM_001326412.1; = p.N291= on NM_014338.3) | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as rs568692291, COSV99837242; called by muse, mutect2, varscan2
- PPIP5K2 | c.3696G>A p.T1232= (on ENST00000358359 / NM_001276277.3; = p.T1211= on NM_015216.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 3/24 reads (13%) | catalogued as rs782198189, COSV58607513; called by muse, mutect2
- PPP1R12A | c.1884G>A p.T628= | Silent (SNP) | VAF 12/20 reads (60%) | catalogued as rs761972298, COSV54108624; called by muse, mutect2, varscan2
- PRPH2 | c.507C>T p.N169= | Silent (SNP) | VAF 32/125 reads (26%) | catalogued as rs143096101, CD033226; called by muse, mutect2, varscan2
- PTPN13 | c.4605G>A p.K1535= (on ENST00000411767 / NM_080683.3; = p.K1516= on NM_006264.3) | Silent (SNP) | VAF 31/86 reads (36%) | catalogued as COSV100364582; called by muse, mutect2, varscan2
- SFSWAP | c.312G>T p.A104= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as COSV99906016; called by muse, mutect2, varscan2
- SHISAL1 | c.234G>T p.A78= | Silent (SNP) | VAF 49/153 reads (32%) | catalogued as COSV101151710, COSV66988206; called by muse, mutect2, varscan2
- STARD13 | c.909C>T p.C303= (on ENST00000336934 / NM_001243476.3; = p.C185= on NM_052851.3) | Silent (SNP) | VAF 7/61 reads (11%) | catalogued as rs368784427; called by muse, mutect2, varscan2
- SYCP2L | c.738G>A p.R246= | Silent (SNP) | VAF 25/83 reads (30%) | catalogued as COSV99305043; called by muse, mutect2, varscan2
- TAS2R60 | c.465C>A p.T155= | Silent (SNP) | VAF 50/198 reads (25%) | catalogued as COSV100223524; called by muse, mutect2, varscan2
- TAS2R60 | c.876C>T p.H292= | Silent (SNP) | VAF 91/197 reads (46%) | catalogued as COSV100223526; called by muse, mutect2, varscan2
- TCF7L2 | c.1527G>T p.S509= (on ENST00000355995 / NM_001367943.1; = p.S486= on NM_030756.5) | Silent (SNP) | VAF 34/109 reads (31%) | catalogued as rs760999129, COSV53342849, COSV99525614; called by muse, mutect2, varscan2
- TEK | c.2583C>A p.A861= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as COSV101193359; called by muse, mutect2, varscan2
- TYK2 | c.354G>T p.R118= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV99314616; called by muse, mutect2, varscan2
- UNC5C | c.879C>A p.L293= | Silent (SNP) | VAF 32/89 reads (36%) | catalogued as COSV101497868; called by muse, mutect2, varscan2
- USP44 | c.1590A>G p.L530= | Silent (SNP) | VAF 21/78 reads (27%) | catalogued as COSV99311766; called by muse, mutect2, varscan2
- ZCCHC2 | c.2775C>G p.A925= | Silent (SNP) | VAF 26/75 reads (35%) | catalogued as COSV99502329; called by muse, mutect2, varscan2
- ZGRF1 | c.2703A>T p.P901= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as COSV100005478; called by muse, mutect2, varscan2
- ZMYND8 | c.756C>T p.I252= (on ENST00000311275 / NM_001363741.2; = p.I272= on NM_012408.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/76 reads (24%) | catalogued as rs768524845, COSV53683528, COSV53695521; called by muse, mutect2, varscan2
- ZNF503 | c.1476G>T p.P492= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as COSV100997997, COSV65307981; called by muse, mutect2, varscan2
- ZP4 | c.270C>A p.T90= | Silent (SNP) | VAF 43/147 reads (29%) | catalogued as COSV100850657; called by muse, mutect2, varscan2
- ADGRL2 | c.398-935dup | Intron (INS) | VAF 12/28 reads (43%) | called by mutect2, pindel, varscan2
- COL11A1 | c.898-224G>C | Intron (SNP) | VAF 25/104 reads (24%) | catalogued as COSV100616107, COSV62172730; called by muse, mutect2, varscan2
- KCNC2 | c.*1916C>A | 3'UTR (SNP) | VAF 10/30 reads (33%) | catalogued as COSV100128653; called by muse, mutect2, varscan2
- SNAPIN | c.-2T>A | 5'UTR (SNP) | VAF 4/19 reads (21%) | catalogued as COSV100721926; called by muse, mutect2, varscan2
- SNORD115-5 | n.6G>T | RNA (SNP) | VAF 74/232 reads (32%) | called by muse, mutect2, varscan2
- SNORD116-11 | n.48A>T | RNA (SNP) | VAF 14/73 reads (19%) | called by muse, mutect2, varscan2
- TNFSF11 | c.*1G>A | 3'UTR (SNP) | VAF 23/53 reads (43%) | catalogued as rs780870683, COSV99520432; called by muse, mutect2, varscan2
